CCDI case PBBVSU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Meningiomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ea99d6f5-a13a-49a9-90b3-da05f8814bc1

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Meningioma, NOS: ICD-O-3 morphology code: 9530/0; Tissue or organ of origin: Meninges, NOS; Age at diagnosis: 10.7 years (3,901 days).

Biospecimens (3 samples)
- Sample 0DIMVV: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIMWQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIMWV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
